Somatic mutation profile of tumor specimen ALCH-B1KE-TTP1-A (aliquot ALCH-B1KE-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1KE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,296 days).
Specimen ALCH-B1KE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801b1233-58bb-45e2-8f99-111ca4b0f8e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KE-NB1-A (Blood Derived Normal), aliquot ALCH-B1KE-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b9989a9-8eac-4e46-ab7f-a0c751f8078b

The open-access MAF lists 286 somatic variants for this specimen: 212 protein-altering or splice-affecting, 39 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 39, Nonsense Mutation 19, Intron 17, Splice Site 7, 3'UTR 5, RNA 5, 5'Flank 3, 3'Flank 3, Translation Start Site 2, 5'UTR 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 21/201 reads (10%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 49/517 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SLC26A4 | c.918+1G>T p.X306_splice | Splice Site (SNP) | VAF 34/428 reads (8%) | catalogued as rs111033245, CS982314; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 17/218 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 19/185 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99504661; called by muse, mutect2
- ACCS | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.293); catalogued as rs946560129; called by muse, mutect2
- ADGRL3 | c.4403G>A p.S1468N (on ENST00000506720 / NM_001322402.2; = p.S1357N on NM_015236.6) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs756197814, COSV72232267; called by muse, mutect2
- ALLC | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294786241; called by muse, mutect2
- B4GALNT3 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs560606072; called by muse, mutect2, varscan2
- BAZ1A | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100701180; called by muse, mutect2
- BICD1 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV55683530; called by muse, mutect2, varscan2
- CDH23 | c.8309C>G p.A2770G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.03); catalogued as COSV56448239; called by muse, mutect2
- CDH4 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV64648910; called by muse, mutect2, varscan2
- CLNK | c.829T>A p.C277S | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs748931035; called by muse, mutect2, varscan2
- CPEB2 | c.2716T>C p.Y906H | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52595270; called by muse, mutect2
- CPED1 | c.2424C>A p.N808K | Missense Mutation (SNP) | VAF 69/657 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV59999192; called by muse, mutect2, varscan2
- CRAT | c.442del p.D148Ifs*5 | Frame Shift Del (DEL) | VAF 23/195 reads (12%) | catalogued as COSV58878405; called by mutect2, pindel, varscan2
- CUBN | c.5386G>T p.V1796L | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.083); catalogued as rs370795698; called by muse, mutect2, varscan2
- DCAF8 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV58783101; called by muse, mutect2
- DCDC1 | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV100664379; called by muse, mutect2
- DENND2A | c.2789G>C p.R930P | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52047117; called by muse, mutect2, varscan2
- DSG1 | c.1565C>A p.T522N | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99936605; called by muse, mutect2
- EYA1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 52/615 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58158041; called by muse, mutect2
- FGD3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs1196180220; called by muse, mutect2
- FLI1 | c.1089C>A p.H363Q | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.371); catalogued as COSV104385894, COSV55643074; called by muse, mutect2, varscan2
- FOXD3 | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1233037853; called by muse, mutect2
- GABRQ | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.288); catalogued as rs1556820429; called by muse, mutect2, varscan2
- GALNS | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1314342; called by muse, mutect2
- GDF2 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as CM138626; called by muse, mutect2, varscan2
- GOLGA1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 71/560 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65228426; called by muse, mutect2, varscan2
- GOLGA8T | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 35/401 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1390331301; called by muse, mutect2
- GRIK5 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53476508; called by muse, mutect2, varscan2
- GRM5 | c.707C>A p.A236E | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV59631715; called by muse, mutect2, varscan2
- HAPLN1 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57148358; called by muse, mutect2
- IGHV1OR21-1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745366252; called by muse, mutect2
- INSC | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.129); catalogued as COSV101089539, COSV65411535; called by muse, mutect2, varscan2
- KLHL1 | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as rs1298236136; called by muse, mutect2, varscan2
- LILRA2 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs957323047; called by muse, mutect2
- MDN1 | c.9245C>T p.P3082L | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764591106; called by muse, mutect2
- MED12 | c.3796C>A p.R1266S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV61341319; called by muse, mutect2, varscan2
- NAV3 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99889220; called by muse, mutect2
- NFATC3 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.753); catalogued as rs147146434; called by muse, mutect2, varscan2
- NOC4L | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1421607238; called by muse, mutect2
- OPHN1 | c.1381A>T p.M461L | Missense Mutation (SNP) | VAF 52/514 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as CM109747; called by muse, mutect2
- OR2L3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63455879; called by muse, mutect2, varscan2
- OR8I2 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV56167102; called by muse, mutect2
- P3H3 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs781968424; called by muse, mutect2
- PCDHGA2 | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV54016678; called by muse, mutect2
- PCDHGA4 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as rs1355845145; called by muse, mutect2
- PGAM2 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV51979231; called by muse, mutect2, varscan2
- PLCB1 | c.1541A>T p.D514V | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV62053433; called by muse, mutect2, varscan2
- PRB3 | c.220C>A p.R74S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99685795; called by mutect2, varscan2
- PRDM14 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 13/200 reads (7%) | catalogued as COSV99399976; called by muse, mutect2
- RIMS3 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1410754396; called by muse, mutect2, varscan2
- RYR2 | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100769515, COSV63668033; called by muse, mutect2, varscan2
- SLC38A10 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55848520; called by muse, mutect2, varscan2
- SLCO1C1 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56873175; called by muse, mutect2, varscan2
- SPATA48 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV51668484; called by muse, mutect2, varscan2
- STAT3 | c.1940A>T p.N647I | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as rs770986654, COSV52882818; called by muse, mutect2, varscan2
- STON2 | c.2088G>C p.W696C (on ENST00000649389 / NM_001366849.2; = p.W639C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50858358; called by muse, mutect2
- STRA6 | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100121125, COSV60588051; called by muse, mutect2, varscan2
- TENM3 | c.3047C>A p.S1016* | Nonsense Mutation (SNP) | VAF 18/494 reads (4%) | catalogued as COSV69312482; called by muse, mutect2
- TRIP13 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51319619, COSV51321412; called by muse, varscan2
- USH2A | c.6383G>C p.C2128S | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as CM104133, CM104134; called by muse, mutect2
- ZNF275 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64705333, COSV99058871; called by muse, mutect2
- ZNF423 | c.3811C>T p.Q1271* (on ENST00000563137 / NM_001379286.1; = p.Q1263* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | catalogued as rs1555503859, COSV99077111; called by muse, mutect2, varscan2
- ZNF594 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 34/374 reads (9%) | catalogued as COSV99077065; called by muse, mutect2
- AATF | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ABCA2 | c.2009G>T p.R670L (on ENST00000614293; = p.R640L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABRAXAS1 | c.893T>G p.V298G | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ADAM12 | c.987G>T p.Q329H | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGB | c.1641T>A p.S547R | Missense Mutation (SNP) | VAF 46/421 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP4 | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD30A | c.148del p.Q50Kfs*8 | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, varscan2
- APOBR | c.2759G>T p.R920M (on ENST00000431282; = p.R929M on NM_018690.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ASXL3 | c.2517A>T p.K839N | Missense Mutation (SNP) | VAF 64/604 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B4 | c.1180T>C p.W394R | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- BLK | c.1029+1G>T p.X343_splice | Splice Site (SNP) | VAF 25/248 reads (10%) | called by muse, mutect2, varscan2
- BRINP3 | c.2192G>T p.R731I | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BSN | c.2575G>T p.E859* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- CALB1 | c.601-3C>A | Splice Region (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.3175G>T p.G1059W (on ENST00000236925 / NM_001297707.2; = p.G1048W on NM_203459.3) | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CCDC126 | c.50T>A p.L17Q | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDK5R2 | c.857T>A p.V286E | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- CDKN2A | c.194_196del p.L65del | In Frame Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- CEACAM16 | c.1201T>A p.Y401N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM18 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CEMIP | c.2849T>A p.M950K | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CFAP47 | c.8384G>T p.W2795L | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- CHST11 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNOT1 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNTNAP5 | c.3571C>A p.H1191N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COG3 | c.1800C>G p.S600R | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- COL11A1 | c.1673C>G p.P558R | Missense Mutation (SNP) | VAF 53/494 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- COTL1 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2
- DCAF8L1 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- DENND5B | c.2644C>A p.H882N | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAAF1 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DNAH9 | c.8625T>A p.N2875K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2
- DNMT3B | c.172A>T p.R58W | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- DTNA | c.1279T>G p.S427A | Missense Mutation (SNP) | VAF 30/607 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- ECPAS | c.3527G>T p.S1176I | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EDA2R | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EFL1 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGFLAM | c.1810+2T>A p.X604_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- EHD3 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ELF2 | c.1181T>C p.V394A (on ENST00000379550 / NM_001331036.2; = p.V334A on NM_006874.4) | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FOXO4 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2
- GABPA | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); called by muse, mutect2
- GDPD4 | c.706A>G p.S236G | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLIS3 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GLIS3 | c.1386C>A p.H462Q | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GNL1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2
- GNL1 | c.640G>T p.G214* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- GP2 | c.566A>T p.K189M (on ENST00000381362 / NM_001007240.3; = p.K186M on NM_001502.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPR158 | c.3522G>T p.W1174C | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIA1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GRM8 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GSC | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2
- HTATSF1 | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2
- IFNW1 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); called by muse, mutect2
- ITSN2 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2
- KIAA0513 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- KRBA1 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- KYNU | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LAMA1 | c.5257G>T p.V1753F | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2
- LAMA4 | c.3273G>T p.M1091I (on ENST00000230538 / NM_001105206.3; = p.M1084I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LARP6 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- LHFPL1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2
- LILRB5 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2
- LINC00922 | n.607+1G>T | Splice Site (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- LRRC4B | c.937T>A p.W313R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP4 | c.1573G>T p.E525* (on ENST00000308370 / NM_001042544.1; = p.E488* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- MAGEB6B | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAGEC1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- MARCKS | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MC4R | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- MCM2 | c.2586G>T p.E862D | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MED12 | c.5470C>A p.P1824T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- MROH2B | c.2885G>A p.G962D | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MTMR11 | c.860+1G>T p.X287_splice (on ENST00000439741 / NM_001145862.2; = p.X215_splice on NM_181873.3) | Splice Site (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- MYH8 | c.2596C>A p.L866I | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- NALCN | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NAV3 | c.5103G>T p.W1701C | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAM2 | c.1573G>T p.V525L | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- NEB | c.14439C>A p.Y4813* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- NHS | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- NLRP11 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- NLRP3 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- NOS2 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OAS2 | c.2080A>T p.R694W | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- OLFML2B | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- OR2B11 | c.47T>A p.F16Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OR2M3 | c.203T>G p.L68R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR2M5 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2
- OR5AP2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5D13 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- OR6C2 | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2
- PA2G4 | c.962T>G p.F321C | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- PATJ | c.2228A>T p.Y743F | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCP4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- PHKB | c.2234G>A p.G745D | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.183); called by muse, mutect2
- PIK3C2G | c.3921C>A p.H1307Q (on ENST00000676171; = p.H1266Q on NM_004570.5) | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.219); called by muse, mutect2
- PIWIL1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 36/371 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PKHD1L1 | c.9015T>A p.C3005* | Nonsense Mutation (SNP) | VAF 30/366 reads (8%) | called by muse, mutect2
- PNPLA5 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- POM121L2 | c.2294C>A p.P765Q | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PRKDC | c.8209G>T p.E2737* | Nonsense Mutation (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- PRSS58 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PSG5 | c.965-1G>A p.X322_splice | Splice Site (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2, varscan2
- PTK2B | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RBFOX1 | c.1074T>A p.N358K | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- REG1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RPH3A | c.1411G>A p.E471K (on ENST00000389385 / NM_001143854.2; = p.E467K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RSPH10B | c.2462A>T p.E821V | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RUBCNL | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXFP3 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RXYLT1 | c.956A>G p.Q319R | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); called by muse, mutect2
- SBF2 | c.2438A>C p.N813T | Missense Mutation (SNP) | VAF 43/454 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.782); called by muse, mutect2
- SHOX2 | c.881C>A p.A294D (on ENST00000441443 / NM_006884.3; = p.A318D on NM_003030.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC11 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC15A1 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- SLC20A1 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.076); called by muse, varscan2
- SLC25A33 | c.443C>G p.P148R | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC40A1 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLFN5 | c.610G>C p.V204L | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- SOCS6 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SORL1 | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- SOX1 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPIN4 | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.029); called by muse, mutect2
- SRP54 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- STAT3 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 31/265 reads (12%) | called by muse, mutect2, varscan2
- TBX5 | c.1019A>T p.K340M | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TEX13C | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TKTL2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.117); called by muse, mutect2
- TRAM1L1 | c.1034G>T p.R345I | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2
- TRIM51GP | c.1164C>A p.H388Q | Missense Mutation (SNP) | VAF 33/549 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.076); called by muse, mutect2
- TUBB8 | c.875A>T p.Q292L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP27X | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- USP8 | c.2957G>C p.S986T | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- VAT1L | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13D | c.7065G>T p.M2355I | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2
- VRK2 | c.676+1G>C p.X226_splice | Splice Site (SNP) | VAF 32/402 reads (8%) | called by muse, mutect2
- ZNF41 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 32/523 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- ZNF727 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- ZNF804B | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 45/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF84 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF99 | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.382); called by muse, mutect2
- ZSCAN5B | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ADAMTS2 | c.621T>G p.R207= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs763850575; called by mutect2, varscan2
- ADGRG7 | c.1953G>T p.L651= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- AGRN | c.5800C>T p.L1934= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as rs1483451253; called by muse, mutect2
- AMELX | c.498C>A p.P166= | Silent (SNP) | VAF 29/270 reads (11%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1107C>A p.T369= (on ENST00000545399 / NM_001256214.2; = p.T356= on NM_152296.5) | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV57488293; called by muse, mutect2, varscan2
- CEP250 | c.6183G>T p.L2061= | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3570C>T p.V1190= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV70509627; called by muse, mutect2
- COL1A2 | c.174C>T p.P58= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- ITGB2 | c.948C>T p.I316= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- KCND1 | c.543G>T p.T181= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99501690; called by mutect2, varscan2
- LRFN5 | c.171G>T p.R57= | Silent (SNP) | VAF 8/236 reads (3%) | called by muse, mutect2
- LRP1B | c.7569C>T p.C2523= | Silent (SNP) | VAF 37/401 reads (9%) | called by muse, mutect2
- LRRC74A | c.543C>A p.I181= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- LRRC9 | c.3765G>T p.V1255= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- MUC16 | c.16041T>A p.P5347= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, varscan2
- MUC17 | c.705C>A p.T235= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- MYO16 | c.2868C>A p.L956= | Silent (SNP) | VAF 56/666 reads (8%) | called by muse, mutect2
- NCAM2 | c.1224A>T p.T408= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2
- NLGN3 | c.357G>C p.L119= | Silent (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- NUAK1 | c.1863G>T p.R621= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV99777081; called by muse, mutect2, varscan2
- NUP35 | c.702A>G p.E234= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as COSV54556991, COSV54558365; called by muse, mutect2
- OR11H6 | c.402A>G p.S134= | Silent (SNP) | VAF 19/235 reads (8%) | called by muse, mutect2
- OR2L13 | c.345C>A p.T115= | Silent (SNP) | VAF 29/359 reads (8%) | catalogued as COSV63562517; called by muse, mutect2
- OXTR | c.471G>A p.V157= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- PCDHA1 | c.2007G>T p.L669= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- PCDHB7 | c.1635G>T p.A545= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as rs1326457745; called by muse, mutect2
- PTCH1 | c.1425G>T p.L475= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- PTPN14 | c.3177G>A p.K1059= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- RHBDF2 | c.2460G>A p.V820= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV51686765; called by muse, mutect2, varscan2
- RIT2 | c.78G>T p.L26= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SPATA18 | c.825C>A p.A275= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV54641488; called by muse, mutect2
- SPATA31A6 | c.3315G>A p.K1105= | Silent (SNP) | VAF 42/284 reads (15%) | called by muse, mutect2, varscan2
- SPIDR | c.1002C>T p.P334= | Silent (SNP) | VAF 19/270 reads (7%) | called by muse, mutect2
- TANC1 | c.702C>T p.S234= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as rs1357148699; called by muse, mutect2
- TLR4 | c.741T>C p.I247= (on ENST00000355622 / NM_138554.5; = p.I207= on NM_003266.4) | Silent (SNP) | VAF 71/463 reads (15%) | called by muse, mutect2, varscan2
- TRPV5 | c.756C>T p.N252= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- TSC22D3 | c.285C>A p.T95= | Silent (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- ZFPM1 | c.2352G>T p.A784= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ZNF248 | c.1332A>T p.T444= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- AC079154.1 | n.1040C>G | RNA (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- AKAP6 | c.3147+49G>C | Intron (SNP) | VAF 12/197 reads (6%) | catalogued as COSV55220303; called by muse, mutect2
- ASIC5 | c.-23C>A | 5'UTR (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- CACNA1G | c.4422+189G>T | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- CFHR5 | c.*46G>T | 3'UTR (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- DGKI | c.2147+6414C>A | Intron (SNP) | VAF 4/95 reads (4%) | called by muse, mutect2
- DNAI2 | c.1211+1812G>T | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- DOT1L | c.2806+139T>A | Intron (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- FLT1 | c.1969+70C>A | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs1331454701; called by muse, mutect2, varscan2
- GBA3 | c.59-8211G>T | Intron (SNP) | VAF 29/263 reads (11%) | called by muse, mutect2, varscan2
- GDPD2 | c.1307+935G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- HDGF | chr1:156752297 G>C | 5'Flank (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.*13G>T | 3'UTR (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- LYZL2 | c.*11G>T | 3'UTR (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-4358C>A | Intron (SNP) | VAF 33/245 reads (13%) | catalogued as rs1393888767; called by mutect2, varscan2
- MGAM | c.4619-11283G>A | Intron (SNP) | VAF 10/227 reads (4%) | catalogued as rs762076455; called by muse, mutect2
- MIR510 | n.66G>T | RNA (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- MIR510 | n.65G>T | RNA (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- MRRFP1 | n.43G>C | RNA (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- NELL1 | c.1549+55073C>A | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.726G>T | RNA (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- PASD1 | c.-23C>T | 5'UTR (SNP) | VAF 23/146 reads (16%) | catalogued as COSV64854735; called by muse, mutect2, varscan2
- PRKACB | c.47-34697A>G | Intron (SNP) | VAF 57/616 reads (9%) | called by muse, mutect2
- PTPRE | c.210-90G>T | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, varscan2
- RN7SL214P | chr15:77915698 G>T | 3'Flank (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159145 C>A | 5'Flank (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159146 C>A | 5'Flank (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- SDCBP2 | c.225+31G>A | Intron (SNP) | VAF 26/282 reads (9%) | catalogued as rs370995021; called by muse, mutect2
- SERPINA6 | c.613+100T>A | Intron (SNP) | VAF 27/264 reads (10%) | catalogued as rs916913875; called by muse, mutect2, varscan2
- SLC4A10 | c.49-60254T>A | Intron (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2
- SUN5 | c.340+45G>T | Intron (SNP) | VAF 22/159 reads (14%) | catalogued as rs1405092758; called by muse, mutect2, varscan2
- TEX35 | chr1:178523318 G>T | 3'Flank (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- TSPAN15 | c.*556A>T | 3'UTR (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- ZNF689 | c.*150G>A | 3'UTR (SNP) | VAF 14/113 reads (12%) | catalogued as rs1417633636; called by muse, mutect2, varscan2
- ZNF793 | chr19:37548322 A>C | 3'Flank (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
